Somatic mutation profile of tumor specimen TCGA-B0-5113-01A (aliquot TCGA-B0-5113-01A-01D-1421-08) from TCGA case TCGA-B0-5113, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.5 years (25,369 days).
Specimen TCGA-B0-5113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bef8df2-dadd-4ec0-96a7-47f433977349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5113-11A (Solid Tissue Normal), aliquot TCGA-B0-5113-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a335f3c-88b4-4596-afbc-51303549fc05

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 22, Silent 8, Frame Shift Del 4, Frame Shift Ins 2, Splice Region 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>T p.X155_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP4E1 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV55914705; called by muse, mutect2, varscan2
- AP4E1 | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV55914719; called by muse, mutect2, varscan2
- C11orf24 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.391); catalogued as COSV58504888; called by muse, mutect2, varscan2
- C17orf49 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs758258644, COSV66080735; called by muse, mutect2, varscan2
- CBLN1 | c.525C>G p.N175K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV54653277; called by muse, mutect2, varscan2
- CFH | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV66405578; called by muse, mutect2, varscan2
- ELFN2 | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV68743701; called by muse, mutect2, varscan2
- FAM83C | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65581887, COSV65583361; called by muse, mutect2
- GABRQ | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); catalogued as COSV100941240, COSV100941474, COSV64780728; called by muse, mutect2, varscan2
- H2BC17 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV100377480, COSV58151903; called by muse, mutect2, varscan2
- LAMP5 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV55714961; called by muse, mutect2, varscan2
- MYPN | c.1918C>A p.P640T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV62731371; called by muse, mutect2, varscan2
- NDUFS1 | c.1448G>T p.R483I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51907645; called by muse, mutect2, varscan2
- NEXN | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV53941691; called by muse, mutect2, varscan2
- NR5A2 | c.462A>C p.E154D (on ENST00000367362 / NM_205860.3; = p.E108D on NM_003822.5) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV52644583; called by muse, mutect2, varscan2
- P2RX1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs748677909, COSV56652722; called by muse, mutect2, varscan2
- REG1B | c.89del p.P30Lfs*38 | Frame Shift Del (DEL) | VAF 45/185 reads (24%) | catalogued as COSV59305662; called by mutect2, pindel, varscan2
- RNF145 | c.485T>G p.L162R (on ENST00000424310 / NM_001199383.2; = p.L190R on NM_144726.2) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.828); catalogued as COSV50864264; called by muse, mutect2, varscan2
- SLC6A13 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV58255089; called by muse, mutect2
- TMEM104 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as rs372516123, COSV59107733; called by muse, mutect2, varscan2
- VANGL1 | c.1493C>A p.P498Q | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59619195, COSV59621777; called by muse, mutect2
- ZFHX4 | c.7819C>G p.R2607G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50480018, COSV50538350, COSV99265401; called by muse, mutect2, varscan2
- ZZZ3 | c.1983A>G p.K661= | Splice Region (SNP) | VAF 36/211 reads (17%) | catalogued as COSV66231079; called by muse, mutect2, varscan2
- ANKRD26 | c.4648del p.T1550Pfs*11 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- B4GALT3 | c.937dup p.S313Ffs*33 | Frame Shift Ins (INS) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- CACNA1B | c.786dup p.V263Rfs*3 | Frame Shift Ins (INS) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.4114A>T p.N1372Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PBRM1 | c.2973del p.K991Nfs*23 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- PXDN | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2
- SENP1 | c.1097del p.L366Wfs*21 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- CACHD1 | c.3099T>C p.C1033= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV51547523; called by muse, mutect2, varscan2
- CACNG2 | c.846C>T p.T282= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV55631821; called by muse, mutect2, varscan2
- COL11A2 | c.4599C>T p.A1533= (on ENST00000341947 / NM_080680.3; = p.A1426= on NM_080679.2) | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV59493316; called by muse, mutect2, varscan2
- DNALI1 | c.99C>T p.Y33= (on ENST00000296218; = p.Y11= on NM_003462.5) | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs774600493, COSV56165501; called by muse, mutect2, varscan2
- DNTTIP2 | c.2205C>T p.I735= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV100785175, COSV63283533; called by muse, mutect2, varscan2
- PRR12 | c.2484C>T p.F828= (on ENST00000615927; = p.F1649= on NM_020719.3) | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV69816561; called by muse, mutect2, varscan2
- TENM4 | c.4722C>T p.N1574= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as COSV53605282; called by muse, mutect2, varscan2
- VPS41 | c.33C>T p.S11= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV56068153; called by muse, mutect2
